Gene-level copy-number profile of tumor specimen TCGA-MQ-A6BS-01A from TCGA case TCGA-MQ-A6BS, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 55.8 years (20,384 days).
Specimen TCGA-MQ-A6BS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-MESO.1e6f9be0-538b-440d-8d01-974ea2326f52.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-MQ-A6BS-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b30ea0a4-c2c0-44ca-a3c9-eac00fc36009

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 3,695; copy number 2: 25,903; copy number 3: 25,637; copy number 4: 3,677; copy number 5: 526; copy number 6: 374.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-MQ-A6BS-01A-12D-A34B-01): tumor purity 0.78, ploidy 2.61, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:50,174,306–50,223,127, 2 genes: ELAVL4-AS1, AL592182.1.
- chr8:2,726,956–2,838,823, 1 gene (within-gene range 0–1): AC246817.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 900 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:75,799,974–84,040,720, 70 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr2:138,863,597–142,131,016, 24 genes, copy number 5 (within-gene range 4–5): RN7SKP286, YY1P2, AHCYP4, AC023468.1, AC013265.1, AC062021.1, AC016710.1, SNORA72, MRPS18BP2, RPL9P13, AC078851.1, RN7SL283P, LINC01853, MTCO1P44, MTND2P19, MTND1P27, LRP1B, AC092156.1, MIR7157, COPRSP1, LRRC57P1, Y_RNA, RNU6-904P, RPS16P3.
- chr6:285,443–10,211,608, 179 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr6:13,357,830–13,711,835, 9 genes, copy number 6: GFOD1, GFOD1-AS1, RPS4XP7, RN7SKP204, SIRT5, AL441883.1, NOL7, RANBP9, Z93020.1.
- chr6:31,639,028–32,749,979, 99 genes, copy number 6 (broad region; genes not listed).
- chr6:33,299,694–35,556,264, 78 genes, copy number 6 (broad region; genes not listed).
- chr6:36,854,827–37,394,734, 16 genes, copy number 6 (within-gene range 4–6): PPIL1, C6orf89, AL122034.1, PI16, MTCH1, FGD2, COX6A1P2, RPL12P2, PIM1, TMEM217, AL353579.1, TBC1D22B, AL096712.1, AL096712.2, RNF8, RN7SL273P.
- chr6:38,168,451–63,779,336, 422 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr6:63,797,189–63,857,769, 3 genes, copy number 5: AL354719.1, SCAT8, GCNT1P4.

Autosomal genes at a single copy (total copy number 1): 1,308. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
